Somatic mutation profile of tumor specimen MBCProject_0063_T3B_WES (aliquot MBCProject_0063_T3B_WES_1) from CMI case MBCProject_0063, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.6 years (15,923 days).
Specimen MBCProject_0063_T3B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65107e5e-4cae-47c7-aadd-22ea103c59ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0063_SALIVA (Saliva), aliquot MBCProject_0063_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2110d9ec-07aa-486f-af0c-828ecda462e5

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Splice Site 1, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- KLF4 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 92/467 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV65928521; called by muse, mutect2, varscan2
- BEND2 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV66217074; called by muse, mutect2, varscan2
- CACNA1H | c.3904G>A p.V1302I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200904795, COSV61990360; called by muse, mutect2, varscan2
- ELOF1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs755727195, COSV52948391; called by muse, mutect2, varscan2
- IGHM | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.2); catalogued as rs868948115; called by muse, mutect2, varscan2
- LMOD1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66172490; called by muse, mutect2
- MTARC1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs866451333, COSV65055695, COSV65056392; called by muse, mutect2
- MYH7 | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP5 | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1248199831; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 18/121 reads (15%) | catalogued as rs146650273; called by pindel, varscan2
- RUBCN | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99584877; called by muse, mutect2
- SIAH3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs1325336463, COSV68553040; called by muse, mutect2
- TBL1XR1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV70501035, COSV99081487; called by muse, mutect2, varscan2
- ZNF618 | c.2719G>A p.A907T (on ENST00000374126 / NM_001318042.2; = p.A814T on NM_133374.2) | Missense Mutation (SNP) | VAF 43/357 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761662307; called by muse, mutect2, varscan2
- DNAH12 | c.5459A>G p.E1820G (on ENST00000351747; = p.E1839G on NM_001366028.2) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.417); called by muse, varscan2
- DPM1 | c.523T>G p.L175V | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, varscan2
- EPHB4 | c.1531T>A p.S511T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2
- HSPG2 | c.10150+2T>C p.X3384_splice | Splice Site (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- PDCD4 | c.1235T>A p.I412N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC10A4 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BEND3 | c.1887C>T p.R629= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs570697259; called by muse, mutect2, varscan2
- DTX1 | c.648C>T p.N216= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- FCRL1 | c.219C>T p.I73= | Silent (SNP) | VAF 48/334 reads (14%) | catalogued as rs763185136, COSV100839709; called by muse, mutect2, varscan2
- MDM4 | c.1101G>A p.S367= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as rs149259264; called by muse, mutect2, varscan2
- P2RX5 | c.1224C>T p.N408= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs201152395, COSV99835861; called by muse, mutect2, varscan2
- ZNF445 | c.3036A>G p.G1012= | Silent (SNP) | VAF 42/367 reads (11%) | called by muse, mutect2, varscan2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 28/273 reads (10%) | catalogued as rs147863190; called by muse, mutect2, varscan2
- CNOT3 | c.2037+215G>A | Intron (SNP) | VAF 31/150 reads (21%) | catalogued as rs371581098; called by muse, mutect2, varscan2
- SNORD52 | chr6:31837351 T>C | 3'Flank (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
